Somatic mutation profile of tumor specimen TCGA-BR-6453-01A (aliquot TCGA-BR-6453-01A-11D-1800-08) from TCGA case TCGA-BR-6453, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 54.9 years (20,061 days).
Specimen TCGA-BR-6453-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12341421-c775-46cb-818e-759ce6769608.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6453-11A (Solid Tissue Normal), aliquot TCGA-BR-6453-11A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04fbb790-3bb0-45ef-914f-ada00a546f57

The open-access MAF lists 195 somatic variants for this specimen: 147 protein-altering or splice-affecting, 45 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 45, Nonsense Mutation 4, RNA 2, Splice Region 1, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCNKB | c.1166G>A p.W389* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as rs1286624133, CM160535, COSV65161671; ClinVar: pathogenic; called by muse, mutect2
- KAT8 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 9/72 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896480; called by muse, mutect2, varscan2
- RNF43 | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV68457845, COSV68459198; called by muse, mutect2
- ABCA5 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as rs140650277, COSV67017175; called by muse, mutect2, varscan2
- AC136428.1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV101434959; called by muse, mutect2
- ACVR2A | c.98T>G p.F33C | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV54027827; called by muse, mutect2
- ADAMTS9 | c.1945T>G p.F649V | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55775681, COSV55781947; called by muse, mutect2, varscan2
- ADGRL4 | c.943T>G p.F315V | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.08); catalogued as COSV66062878; called by muse, mutect2
- ADGRL4 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as COSV66064839; called by muse, mutect2, varscan2
- AMER1 | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV57666161; called by muse, mutect2, varscan2
- ANXA1 | c.799A>G p.I267V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.026); catalogued as COSV57412439; called by muse, mutect2
- API5 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.897); catalogued as COSV66634720; called by muse, mutect2
- ARMC4 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs138508233; called by muse, mutect2, varscan2
- ATP6V1C2 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.03); catalogued as COSV55364172; called by muse, mutect2
- BNC2 | c.2071T>C p.F691L | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV66155230; called by muse, mutect2
- CCNA1 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV55223544; called by muse, mutect2
- CD1E | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100937010, COSV63770217; called by muse, mutect2
- CDH12 | c.1835T>C p.L612P | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66412479, COSV66440192; called by muse, mutect2
- CDH23 | c.5465G>A p.C1822Y | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as rs1200284846, COSV56484634; called by muse, mutect2, varscan2
- CEACAM3 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs782581482, COSV55762116; called by muse, mutect2, varscan2
- CELSR2 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780159848, COSV54778194, COSV54779601; called by muse, mutect2, varscan2
- CENPO | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.325); catalogued as rs758593609, COSV53171792; called by mutect2, varscan2
- CFAP54 | c.5083A>C p.N1695H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV61574665; called by muse, mutect2
- CHD4 | c.2399G>A p.R800H (on ENST00000357008 / NM_001363606.2; = p.R813H on NM_001273.5) | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58908829; called by muse, mutect2, varscan2
- CHRM2 | c.820T>A p.C274S | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as COSV57782167, COSV57785049; called by muse, mutect2
- CILP2 | c.2273T>C p.V758A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.102); catalogued as COSV52279499; called by muse, mutect2, varscan2
- CLEC2B | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57310307; called by muse, mutect2, varscan2
- CLIC4 | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.496); catalogued as COSV65527439; called by muse, mutect2
- CMAS | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as COSV57557418; called by muse, mutect2, varscan2
- CNTLN | c.2813A>G p.K938R | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV52093458, COSV99262418; called by muse, mutect2
- CNTN3 | c.830A>C p.K277T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV55181896; called by muse, mutect2, varscan2
- COL11A1 | c.5128T>G p.F1710V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as COSV62171941; called by muse, mutect2, varscan2
- COLEC12 | c.1840T>G p.F614V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV68373157; called by muse, mutect2, varscan2
- CPAMD8 | c.1577C>T p.P526L (on ENST00000651564; = p.P479L on NM_015692.5) | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52238820; called by muse, mutect2
- CSMD1 | c.7274A>C p.K2425T (on ENST00000520002; = p.K2424T on NM_033225.6) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV59314561; called by muse, mutect2
- CYP4A22 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as rs575378698, COSV53742011; called by muse, mutect2, varscan2
- DDIT4L | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56767953; called by muse, mutect2, varscan2
- DHX36 | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV57676471; called by muse, mutect2, varscan2
- DYNC2H1 | c.7097T>G p.L2366R | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV62104103; called by muse, mutect2, varscan2
- EGFLAM | c.1753G>T p.A585S | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59314299; called by muse, mutect2, varscan2
- ELMO1 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV60320327, COSV60323716; called by muse, mutect2, varscan2
- EPHA2 | c.843T>A p.F281L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV64454468; called by muse, mutect2, varscan2
- EZHIP | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs782520788, COSV100539575, COSV57955400, COSV57956449; called by muse, mutect2
- FAM153B | c.561C>T p.N187= (on ENST00000253490; = p.N110= on NM_001265615.1) | Splice Region (SNP) | VAF 9/138 reads (7%) | catalogued as rs200598706, COSV53687547; called by muse, mutect2
- FAR2 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51726040; called by muse, mutect2, varscan2
- FAT4 | c.7T>G p.L3V | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as COSV67886986; called by muse, mutect2, varscan2
- FEV | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767664032, COSV55387327; called by muse, mutect2, varscan2
- FGFR1 | c.973G>A p.V325M (on ENST00000447712 / NM_023110.3; = p.V323M on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58342379; called by muse, mutect2, varscan2
- FMOD | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1325044595, COSV61609652, COSV61610029; called by muse, mutect2, varscan2
- GABRA5 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV59476292; called by muse, mutect2, varscan2
- GABRA6 | c.77A>C p.N26T | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as COSV50890984; called by muse, mutect2
- GALNT17 | c.845A>C p.N282T | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61185250; called by muse, mutect2, varscan2
- GHR | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV50125805; called by muse, mutect2, varscan2
- GPC6 | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV65532507; called by muse, mutect2
- GPR158 | c.1321T>G p.F441V | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66279977; called by muse, mutect2, varscan2
- GPR158 | c.2444A>C p.K815T | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as COSV66279984; called by muse, mutect2, varscan2
- GRIK2 | c.149T>G p.M50R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV59763271; called by muse, mutect2, varscan2
- GRIN2A | c.4126C>T p.R1376C | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs1426934537, COSV58023359, COSV58024387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM2 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.614); catalogued as rs751842471, COSV56584965; called by muse, mutect2, varscan2
- HFM1 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV54035408; called by muse, mutect2, varscan2
- IL21R | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.192); catalogued as rs779279193, COSV61972162; called by muse, mutect2, varscan2
- KCNH8 | c.3202T>G p.L1068V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as COSV60474103; called by muse, mutect2, varscan2
- KCNJ8 | c.652A>C p.S218R | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53717993; called by muse, mutect2, varscan2
- KCNN2 | c.836T>G p.L279R (on ENST00000264773; = p.L491R on NM_021614.4) | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53297270; called by muse, mutect2, varscan2
- KDM3B | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.959); catalogued as COSV58694364; called by muse, mutect2
- KHDRBS2 | c.250A>G p.R84G | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV55447094, COSV55484583; called by muse, mutect2, varscan2
- KIAA2026 | c.2630A>C p.K877T | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV67357124; called by muse, mutect2, varscan2
- KIF2B | c.1534T>G p.S512A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV52128734, COSV52129862; called by muse, mutect2, varscan2
- LAGE3 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.313); catalogued as COSV62074396; called by muse, mutect2, varscan2
- LAMA1 | c.502A>G p.R168G | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs764099878, COSV67531333, COSV67543103; called by muse, mutect2, varscan2
- LRP12 | c.2279T>C p.L760P | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52633641; called by muse, mutect2, varscan2
- LRP1B | c.9071A>G p.E3024G | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.815); catalogued as COSV67184236; called by muse, mutect2
- LRRC30 | c.254T>G p.V85G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.061); catalogued as COSV67302183; called by muse, mutect2, varscan2
- LRRIQ3 | c.1455A>C p.Q485H | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV63048858; called by muse, mutect2, varscan2
- LUZP2 | c.804A>C p.Q268H | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100419385, COSV61195719; called by muse, mutect2, varscan2
- MAGEA10 | c.1072A>G p.S358G | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as rs367772567, COSV54883259, COSV54884806, COSV54885579; called by muse, mutect2, varscan2
- MEP1A | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV57922148; called by muse, mutect2, varscan2
- MSR1 | c.490T>C p.S164P | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV50527951; called by muse, mutect2
- MUC16 | c.5800T>G p.L1934V | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67487641; called by muse, mutect2, varscan2
- MYRIP | c.1907A>C p.K636T | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV56870516; called by muse, mutect2, varscan2
- NAB1 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs772814531, COSV61609310; called by muse, mutect2, varscan2
- NBEA | c.6990A>C p.E2330D | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV59815295; called by muse, mutect2, varscan2
- NBEAL2 | c.7864C>T p.R2622C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1259998992, COSV52762270; called by muse, mutect2, varscan2
- NDST4 | c.1052A>C p.K351T | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52109442; called by muse, mutect2, varscan2
- NECAB1 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.143); catalogued as COSV70243484; called by muse, mutect2
- NLRP7 | c.1381A>C p.K461Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV100051995; called by muse, mutect2, varscan2
- OPRK1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200420778, COSV55573239; called by muse, mutect2, varscan2
- OPRK1 | c.439T>G p.F147V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55569305; called by muse, mutect2, varscan2
- OR12D2 | c.247T>G p.F83V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV65829842; called by muse, mutect2, varscan2
- OR4A5 | c.279A>C p.Q93H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV60521832, COSV60521913; called by muse, mutect2, varscan2
- OR51A7 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV63787997, COSV63788424; called by muse, mutect2, varscan2
- OR52E8 | c.760T>G p.L254V | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV66211375; called by muse, mutect2
- OR56A4 | c.995A>C p.N332T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58111490; called by muse, mutect2, varscan2
- OR5W2 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV60614714, COSV60614862; called by muse, mutect2, varscan2
- PAX3 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs372190620; called by muse, mutect2
- PCDH11X | c.749A>C p.K250T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV53490826, COSV53497035; called by muse, mutect2, varscan2
- PCDHB6 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.332); catalogued as rs782308444, COSV50719043; called by muse, mutect2, varscan2
- PDLIM4 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs755408398, COSV53805151; called by muse, mutect2
- PPP2R2C | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV59444259; called by muse, mutect2, varscan2
- PREX2 | c.4113A>C p.E1371D | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55750210, COSV55795331; called by muse, mutect2
- PRICKLE2 | c.2243G>A p.R748H (on ENST00000295902; = p.R692H on NM_198859.4) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); catalogued as COSV55770758; called by muse, mutect2, varscan2
- PSG5 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 33/427 reads (8%) | catalogued as rs1421766335, COSV100742611; called by muse, mutect2, varscan2
- PTPRC | c.2691A>T p.Q897H | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61405854, COSV61412086, COSV61419400; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs1177781566, COSV62786610; called by muse, mutect2, varscan2
- RIMS2 | c.1264A>C p.S422R (on ENST00000666250 / NM_001348490.2; = p.S230R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.889); catalogued as COSV51681237, COSV51715857; called by muse, varscan2
- RIT2 | c.594A>C p.K198N | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV58660464, COSV58674553; called by muse, mutect2, varscan2
- RNF213 | c.2520G>T p.L840F | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.103); catalogued as COSV100173248; called by muse, mutect2, varscan2
- RORB | c.469G>A p.V157I (on ENST00000396204 / NM_001365023.1; = p.V146I on NM_006914.4) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs975708949, COSV65335600; called by muse, mutect2
- RPUSD2 | c.1181G>A p.W394* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as rs1346627084, COSV59766214; called by muse, mutect2, varscan2
- RUBCNL | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59793142; called by muse, mutect2, varscan2
- SCN1A | c.2972T>G p.L991R (on ENST00000303395 / NM_001202435.3; = p.L980R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CX126552, COSV57683861; called by muse, mutect2, varscan2
- SEC24B | c.2923T>G p.L975V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs777778221, COSV54505012; called by muse, mutect2, varscan2
- SECISBP2L | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs762754299, COSV55932479, COSV55937125; called by muse, mutect2, varscan2
- SLC32A1 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV54145528; called by muse, mutect2, varscan2
- SLITRK6 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.344); catalogued as COSV68391419; called by muse, mutect2, varscan2
- SNRPA | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV54680507, COSV54682419; called by muse, mutect2, varscan2
- SNRPN | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57593843, COSV57596019; called by muse, mutect2, varscan2
- SOX7 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs775918915, COSV58730250; called by muse, mutect2, varscan2
- SPOCD1 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs769296757, COSV57099248; called by muse, mutect2, varscan2
- SRCAP | c.2630+1G>A p.X877_splice | Splice Site (SNP) | VAF 20/147 reads (14%) | catalogued as COSV52679342; called by muse, mutect2, varscan2
- STXBP5L | c.390T>G p.S130R | Missense Mutation (SNP) | VAF 27/306 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV56502232, COSV56514489; called by muse, mutect2
- STXBP5L | c.1880T>G p.L627R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56530688; called by muse, mutect2, varscan2
- SULF1 | c.1689A>C p.E563D | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.028); catalogued as COSV52673317; called by muse, mutect2, varscan2
- TEKT3 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs776165938, COSV58629436; called by muse, mutect2
- TENM1 | c.3700A>C p.S1234R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.063); catalogued as COSV64435788, COSV64440705; called by muse, mutect2, varscan2
- TENT5D | c.272T>A p.L91H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV57638755; called by muse, mutect2, varscan2
- TESPA1 | c.944T>G p.V315G (on ENST00000316577 / NM_001098815.3; = p.V177G on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57256990; called by muse, mutect2, varscan2
- TLR4 | c.1459T>G p.F487V (on ENST00000355622 / NM_138554.5; = p.F447V on NM_003266.4) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV62923063, COSV62924683; called by muse, mutect2, varscan2
- TMEM176B | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50244299; called by muse, mutect2
- TMPRSS6 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs188371820, COSV60982929; called by mutect2, varscan2
- TRIM51 | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV55270220; called by mutect2, varscan2
- TRPC4 | c.1841A>C p.N614T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59014135; called by muse, mutect2, varscan2
- TTN | c.48357A>C p.E16119D (on ENST00000591111; = p.E8695D on NM_003319.4) | Missense Mutation (SNP) | VAF 29/159 reads (18%) | PolyPhen benign (0.074); catalogued as COSV59905709; called by muse, mutect2, varscan2
- UNC45B | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs910854904, COSV52099807; called by muse, mutect2, varscan2
- UNC5C | c.1556A>C p.N519T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV71659157; called by muse, mutect2, varscan2
- WWP2 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs751715302, COSV63127060; called by muse, mutect2, varscan2
- ZC3H13 | c.1774T>G p.Y592D | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV54461554; called by muse, mutect2
- ZMAT5 | c.194A>C p.Q65P | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as COSV60244051; called by muse, mutect2
- ZNF311 | c.1541T>A p.L514H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65853338; called by muse, mutect2, varscan2
- ZNF43 | c.256T>G p.F86V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV61684157, COSV61685547; called by muse, mutect2
- ZNF486 | c.1087T>C p.S363P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV58721860; called by muse, mutect2, varscan2
- ZNF649 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.646); catalogued as COSV56817446; called by muse, mutect2, varscan2
- ZNF804A | c.2382A>C p.E794D | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV56456038, COSV56467191; called by muse, mutect2
- ZNF99 | c.985A>G p.R329G | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as COSV68056468; called by muse, mutect2
- CADPS2 | c.2766del p.K922Nfs*51 | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | called by pindel, varscan2*
- IGKV1D-42 | c.345T>G p.S115R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2
- PRAMEF15 | c.1104A>C p.Q368H | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- ANLN | c.3315T>C p.V1105= | Silent (SNP) | VAF 56/415 reads (13%) | catalogued as COSV56078855; called by muse, mutect2, varscan2
- CACNA1I | c.2481C>T p.L827= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV60816388; called by muse, mutect2
- CDH18 | c.2211T>C p.T737= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV56953549; called by muse, mutect2, varscan2
- CEP112 | c.972T>G p.R324= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV67144076; called by mutect2, varscan2
- CFAP221 | c.1602G>T p.L534= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as COSV54661575; called by muse, mutect2, varscan2
- COL12A1 | c.6306A>G p.G2102= | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as COSV59405366; called by muse, mutect2, varscan2
- COL4A6 | c.1782A>G p.G594= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV57875077; called by muse, mutect2, varscan2
- DCDC1 | c.21A>G p.E7= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV60855643; called by muse, mutect2, varscan2
- DNAH11 | c.9663C>A p.A3221= | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as COSV60966295, COSV60975820; called by muse, mutect2, varscan2
- EPHA3 | c.138T>C p.S46= | Silent (SNP) | VAF 12/175 reads (7%) | catalogued as COSV60722831; called by muse, mutect2
- EPHA5 | c.1348T>C p.L450= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV56646682; called by mutect2, varscan2
- ERO1B | c.663G>A p.A221= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs1415745493, COSV59242118; called by muse, mutect2, varscan2
- FAT3 | c.7680G>T p.R2560= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV53162176; called by muse, mutect2, varscan2
- FAT4 | c.8328T>C p.S2776= | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as COSV58673996, COSV58703577, COSV58708958; called by muse, mutect2
- FMN2 | c.1350C>A p.S450= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs377516551, COSV60424626; called by mutect2, varscan2
- FMN2 | c.4872A>G p.Q1624= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as COSV60422561, COSV60449037; called by muse, mutect2, varscan2
- FPR2 | c.351T>G p.G117= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV60673275, COSV60674225; called by muse, mutect2, varscan2
- FSTL5 | c.1008A>G p.Q336= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as COSV60187025; called by muse, mutect2, varscan2
- FUT7 | c.582G>A p.A194= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs768075189, COSV55805635; called by muse, mutect2, varscan2
- GRM6 | c.1248C>T p.H416= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs755296288, COSV51448595; called by muse, mutect2, varscan2
- HLA-DOA | c.129C>T p.G43= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs574592087, COSV57715439; called by muse, mutect2, varscan2
- IRS4 | c.3741T>C p.D1247= | Silent (SNP) | VAF 5/119 reads (4%) | catalogued as COSV64535574; called by muse, mutect2
- ITGB4 | c.1170C>T p.F390= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV52331492; called by muse, mutect2, varscan2
- KCNAB3 | c.1200G>A p.P400= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV58140425; called by muse, mutect2
- KIF21A | c.4065T>C p.S1355= (on ENST00000361418 / NM_001378440.1; = p.S1342= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV62776824; called by muse, mutect2, varscan2
- LRP1B | c.10240T>C p.L3414= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as COSV67263549; called by muse, mutect2, varscan2
- MPPED1 | c.282C>T p.C94= | Silent (SNP) | VAF 23/169 reads (14%) | catalogued as rs771013621, COSV61988565; called by muse, mutect2, varscan2
- MROH5 | c.1383G>A p.E461= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV71302624; called by muse, mutect2, varscan2
- MYH6 | c.513C>T p.N171= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV62453832; called by muse, mutect2
- NOVA1 | c.564G>A p.G188= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as COSV57485790; called by muse, mutect2, varscan2
- OR10Z1 | c.261G>A p.G87= | Silent (SNP) | VAF 31/320 reads (10%) | catalogued as COSV63525491; called by muse, mutect2, varscan2
- OTX1 | c.759G>A p.A253= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs541502870, COSV56995851; called by muse, mutect2, varscan2
- PCDHGA8 | c.438G>A p.A146= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV54013785; called by muse, mutect2, varscan2
- PLXDC2 | c.895A>C p.R299= | Silent (SNP) | VAF 17/168 reads (10%) | catalogued as COSV65908031; called by muse, mutect2
- PRR16 | c.774T>A p.P258= (on ENST00000407149 / NM_001300783.2; = p.P235= on NM_016644.2) | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV101086655; called by muse, mutect2, varscan2
- RAB39A | c.387T>C p.C129= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV57695407; called by muse, mutect2, varscan2
- RASA2 | c.1914C>T p.L638= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs138963413; called by muse, mutect2, varscan2
- RASGRF1 | c.318C>A p.A106= | Silent (SNP) | VAF 21/177 reads (12%) | catalogued as COSV69182401; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, varscan2
- RIMS2 | c.4228T>C p.L1410= (on ENST00000666250 / NM_001348490.2; = p.L981= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs1234270181, COSV51715926; called by muse, mutect2, varscan2
- SMAD9 | c.297G>A p.P99= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs559936906, COSV63204822; called by muse, mutect2, varscan2
- TDO2 | c.939T>C p.S313= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs1386721916, COSV72542830; called by muse, mutect2, varscan2
- TTN | c.68829A>G p.Q22943= (on ENST00000591111; = p.Q15519= on NM_003319.4) | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV60236562; called by muse, mutect2
- ZNF674 | c.1450C>T p.L484= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV70378502, COSV70379675; called by muse, mutect2, varscan2
- ZNF883 | c.705A>G p.K235= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as rs1432424627, COSV71308864, COSV71309211; called by muse, mutect2
- CLCA3P | n.768T>C | RNA (SNP) | VAF 6/40 reads (15%) | catalogued as rs1165133814; called by muse, mutect2, varscan2
- TMEM99 | n.370T>C | RNA (SNP) | VAF 13/89 reads (15%) | catalogued as rs370428508; called by muse, mutect2, varscan2
- TPTE2 | c.1395+686G>C | Intron (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2
